Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6013, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6013-01A (Primary Tumor).

[page 1 of 8]
Pathology Report [REDACTED] **CORRECTED**

Report Type Pathology Report
Date of Event [REDACTED]
Sex [REDACTED]
Authored by [REDACTED]
Hosp/Group [REDACTED]
Record Status CORRECTED

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Malignant neoplasm mouth.
PROCEDURE: Neck dissection/mandibulectomy.
SPECIFIC CLINICAL QUESTION: Unanswered.
OUTSIDE TISSUE DIAGNOSIS: Unanswered.
PRIOR MALIGNANCY: Unanswered.
CHEMORADIATION THERAPY: Unanswered.
ORGAN TRANSPLANT: Unanswered.
IMMUNOSUPPRESSION: Unanswered.
OTHER DISEASES: Unanswered.
[REDACTED]

ADDENDA:

Addendum

PROBE: LSI EGFR/CEP7 Dual-Color Probe ([REDACTED])
Cytogenetic Location: 7p12 / 7p11.1-q11.1
EGFR FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.
Number of cells analyzed: 61
Ratio EGFR/CEP7: 1.04
High Polysomy: 0%
SNR (signal to nucleus ratio): 1.8
Low Polysomy: 0%
Trisomy: 0%
Disomy: 61(100%)
EGFR FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the EGFR SpectrumOrange and the CEP7 SpectrumGreen probes.
EGFR FISH positive:
High Polysomy: > four gene copies in > 40% of cells
Gene Amplification: Ratio gene/chromosome more than two or > 15 gene copies in > 10% of cells
EGFR FISH negative:
Disomy: < two gene copies in more than 90% of the cells
Trisomy: three gene copies in more than 10% of cells
Low Polysomy: > four gene copies in more than 10% but less than 40% of cells
References:

[REDACTED]

[page 2 of 8]
[REDACTED]

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

Addendum

The following immunohistochemical stains and in-situ hybridization were completed on the mandibulectomy specimen and were as follows:

STAIN	RESULT
EGFR	3+ membranous.
P16	Negative.
HPV in situ	Negative.

[REDACTED]

[REDACTED]

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, LEVEL 1A, SELECTIVE DISSECTION

TWO LYMPH NODES, NO TUMOR PRESENT (0/2).

PART 2: MANDIBLE AND PERIMANDIBULAR SOFT TISSUE, SEGMENTAL MANDIBULECTOMY

A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATE TO POORLY DIFFERENTIATED (2.8 CM), INVOLVING THE RIGHT LATERAL GINGIVA, BUCCAL MUCOSA, PERIMANDIBULAR SOFT TISSUE AND FOCALLY, MANDIBULAR BONE (see comment).

B. BONE MARGINS ARE FREE OF CARCINOMA. FOR ALL OTHER MARGINS SEE PARTS 3-6, 9, 11.

C. NO PERINEURAL INVASION.

D. METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OUT OF SEVEN LYMPH NODES WITH EXTRACAPSULAR SPREAD (LARGEST: 3.8 CM) (2/7).

E. PATHOLOGICAL STAGE: pT4a N2b.

F. UNREMARKABLE SUBMANDIBULAR GLAND.

G. BENIGN PAROTID ACINAR INCLUSIONS.

PART 3: BONE MARROW, POSTERIOR MANDIBULAR MARGIN, EXTRACTION
NO TUMOR PRESENT.

PART 4: BONE MARROW, ANTERIOR MANDIBULAR MARGIN, EXTRACTION
NO TUMOR PRESENT.

PART 5: MOUTH, RIGHT FLOOR, EXCISION
NO TUMOR PRESENT.

PART 6: BUCCAL MUCOSA, RIGHT MARGIN, EXCISION
NO TUMOR PRESENT.

PART 7: POSTERIOR MUCOSA, RIGHT MARGIN, EXCISION

[page 3 of 8]
SQUAMOUS MUCOSA WITH MODERATE TO FOCALLY SEVERE DYSPLASIA.
PART 8: LYMPH NODES, LEVELS 2-4, RIGHT, SELECTIVE DISSECTION
NINETEEN LYMPH NODES, NO TUMOR PRESENT (0/19).
PART 9: LATERAL MUCOSA, NEW POSTERIOR MARGIN, EXCISION
NO TUMOR PRESENT.
PART 10: MEDIAL MUCOSA, NEW POSTERIOR MARGIN, EXCISION
SQUAMOUS MUCOSA WITH MILD DYSPLASIA.
PART 11: FINAL POSTERIOR MEDIAL MARGIN, EXCISION
NO TUMOR PRESENT.

COMMENT:

Ancillary studies are to follow in an addendum.

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in 11 parts.

Part 1 is received fresh labeled with the patient's name, initials xxx, and labeled "neck dissection level 1A". Received is a fibroadipose tissue measuring 4.8 x 1.2 x 0.5 cm. On serial sectioning, there are possible lymph nodes ranging in size from 0.1 to 0.3 cm. The entire specimen is submitted in cassettes 1A through 1C.

Part 2 is received fresh labeled with the patient's name, initials xxx, and labeled "right composite resection". Received is a mandibulectomy specimen measuring 7.0 cm superior to inferior x 7.3 cm anterior to posterior x 4.5 cm medial to lateral. The specimen includes mandibular bone, gingiva, lateral soft tissue, medial soft tissue, submandibular gland, three teeth and lymph nodes.

There is a white firm mass measuring 2.8 x 2.0 x 2.0 cm involving the lateral portion of the gingiva and the lateral buccal mucosa. On sectioning of the mandibular bone, the lesion may grossly involve the mandibular bone. The lesion does not appear to involve the medial side of the mandibular bone nor medial soft tissues grossly. The lesion is 0.2 cm from the lateral soft tissue margin and 0.1 cm from the posterior soft tissue margin.

There is a lymph node adjacent to the submandibular gland which grossly appears involved. This lymph node measures 3.8 x 2.5 x 3.2 cm. This lymph node is necrotic, cystic and filled with yellow fluid. It is located between the mandible and the submandibular gland approximately 0.3 cm from the inferior mandible and grossly abuts but is separated from the submandibular gland by soft tissue. The submandibular gland measures 3.0 x 2.0 x 2.0 cm. It does not appear involved by the lesion grossly. There is also another lymph node that grossly appears involved measuring 1.8 x 1.3 x 1.2 cm. It is located in the anterior inferior soft tissue and grossly appears to have some extranodal extension.

Other possible lymph nodes are found in the soft tissue. These lymph nodes are tan, do not grossly appear to be involved, and range in size from 0.6 to 1.0 cm.

[page 4 of 8]
Digital photographs are taken.

Tissue is banked for [REDACTED]

Ink Code:

Black external surface of the specimen

Red tissue banked.

Cassette Code:

- 2A - medial mucosal edge
- 2B - posterior mucosal edge
- 2C - lateral mucosal edge
- 2D - tumor to lateral soft tissue margin
- 2E - representative tumor sections
- 2F - posterior soft tissue margin with tumor
- 2G - medial soft tissue margin
- 2H - submandibular gland in relation to largest lymph node
- 2I-2J - largest lymph node with neighboring representative soft tissue
- 2K-2L - representative of the second largest lymph node
- 2M - one lymph node bisected
- 2N - one lymph node bisected
- 2O - possible lymph nodes
- 2P - representative submandibular gland
- 2QDR - anterior bone margin
- 2RDR - posterior bone margin
- 2SDR-2TDR - tumor with relation to the mandible.

Part 3 is received fresh labeled with the patient's name, initials xxx, and labeled "posterior mandibular bone marrow margin". Received is a 0.4 x 0.1 x 0.1 cm bone marrow specimen. It was submitted for intraoperative consultation and is resubmitted in 3AFS.

Part 4 is received fresh labeled with the patient's name, initials xxx, and labeled "anterior mandibular bone marrow margin". Received is less than 0.1 x 0.1 x 0.1 cm bone marrow specimen. It was submitted for intraoperative consultation and is resubmitted in cassette 4AFS.

Part 5 is received fresh labeled with the patient's name, initials xxx, and labeled "right floor of mouth, stitch marks anterior". Received is a 2.0 x 0.4 x 0.2 cm soft tissue fragment. It was received for intraoperative consultation and is resubmitted in 5AFS.

Part 6 is received fresh labeled with the patient's name, initials xxx, and labeled "right buccal mucosal margin, stitch marks anterior". Received is a 3.5 x 0.4 x 0.2 cm soft tissue fragment. It was submitted for intraoperative consultation and is resubmitted in cassette 6AFS.

Part 7 is received fresh labeled with the patient's name, initials xxx, and labeled "right posterior mucosal margin, stitch marks lateral". Received is a 4.0 x 0.4 x 0.2 cm soft tissue fragment. It was received for intraoperative consultation and is resubmitted in 7AFS.

Part 8 is received fresh labeled with the patient's name, initials xxx, and labeled "right neck dissection, levels 2 through 4". Received are unoriented fragments of fibroadipose tissue in aggregate measuring 3.2 x 1.2 x 1.3 cm and an unoriented main fragment measuring 10.5 x 4.1 x 1.1 cm. The fragments and the main specimen are serially sectioned for lymph nodes. Possible lymph nodes are found ranging from 0.3 cm to 2.2 cm. The largest lymph node is found in the mid two-thirds region of the main fragment.

Cassette Code:

- 8A - possible lymph nodes from the fragments of tissue received
- 8B-8C - possible lymph nodes from the first one-third of the main fragment

[page 5 of 8]
8D-8G - possible lymph nodes from the second third of the main specimen (8D one lymph node sectioned, 8E-8F - one lymph node fragmented, 8G - possible lymph nodes)

8H - possible lymph nodes from the last third of the main fragment.

Part 9 is received fresh labeled with the patient's name, initials xxx, and labeled "new posterior lateral mucosal margin, inked margin is the true margin". Received is a soft tissue fragment measuring 1.5 x 0.5 x 0.1 cm. It was received for intraoperative consultation and is resubmitted in cassette 9AFS.

Part 10 is received fresh labeled with the patient's name, initials xxx, and labeled "new posterior medial mucosal margin, inked margin is the true margin". Received are two soft tissue fragments, one measuring 0.8 x 0.3 x 0.1 cm and the other measuring 0.3 x 0.2 x 0.1 cm. It was received for intraoperative consultation and is resubmitted in cassette 10AFS.

Part 11 is received fresh labeled with the patient's name, initials xxx, and labeled "final posterior medial margin, inked margin is true margin". Received is a 1.8 x 0.5 x 0.2 cm soft tissue fragment. One side is inked blue. The entire specimen is submitted in cassette 11A with the inked side down.

[REDACTED]

INTRAOPERATIVE CONSULTATION:

3A: POSTERIOR MANDIBLE BONE MARROW MARGIN, MANDIBULECTOMY (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

4A: ANTERIOR MANDIBULAR BONE MARROW MARGIN, MANDIBULECTOMY (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT.

C. VERY SMALL SPECIMEN ([REDACTED]).

5A: RIGHT FLOOR OF MOUTH, MANDIBULECTOMY (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

6A: RIGHT BUCCAL MUCOSAL MARGIN, MANDIBULECTOMY (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

7A: POSTERIOR MUCOSAL MARGIN, MANDIBULECTOMY (frozen section)

A. MALIGNANT.

B. THE MEDIAL PORTION OF THIS SPECIMEN CONTAINS A MODERATE TO SEVERE DYSPLASIA ([REDACTED]).

9A; NEW POSTERIOR LATERAL MUCOSAL MARGIN, MANDIBULECTOMY (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

10A: NEW POSTERIOR MEDIAL MUCOSAL MARGIN, MANDIBULECTOMY (frozen section)

A. DEFER.

B. MILD TO MODERATE DYSPLASIA ([REDACTED]).

[REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

[page 6 of 8]
The testing was developed and its performance characteristics determined by the [REDACTED]h, Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND

TUMORS

SPECIMEN TYPE: Resection: mandibectomy

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 2.8 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT4a

REGIONAL LYMPH NODES (pN): pN2b

Number of regional lymph nodes examined: 26

Number of regional lymph nodes involved: 2

Extra-capsular extension of nodal tumor: Present

DISTANT METASTASIS (pM): pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION: Absent

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Neck Dissection Level 1A

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 2: Right Composite Resection

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E Recut x 1 E

IEGFR x 1 E

IBNKNC x 1 E

IBNKNC x 1 E

IBNKNC x 1 E

IBNKNC x 1 E

IBNKNC x 1 E

IBNKNC x 1 E

[page 7 of 8]
H&E x 1 E
HPV x 1 E
IISH x 1 E
IISH x 1 E
P16 x 1 E
V-EGFR x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O
H&E x 1 P

Decal x 1
H&E x 1
Decal x 1
H&E x 1
Decal x 1

RHHE Lev ___ x 1
RHHE Lev ___ x 1
RHHE Lev ___ x 1

H&E x 1
Decal x 1
H&E x 1

Part 3: Posterior Mandibular Bone Marrow Margin

Taken: Received:

Stain/cnt Block

H&E x 1 AFS

Part 4: Anterior Mandibular Bone Marrow Margin

Taken: Received:

Stain/cnt Block

HBKNC x 1 AFS

HBKNC x 1 AFS

HBKNC x 1 AFS

HBKNC x 1 AFS

H&E x 1 AFS

Part 5: Right Floor of Mouth

Taken: Received:

Stain/cnt Block

H&E x 1 AFS

Part 6: Right Buccal Mucosal Margin

Taken: Received:

Stain/cnt Block

H&E x 1 AFS

Part 7: Right Posterior Mucosal Margin

Taken: Received:

Stain/cnt Block

H&E x 1 AFS

Part 8: Right Neck Dissection Levels 2-4

[page 8 of 8]
Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

Part 9: New Posterior Lateral Mucosal Margin

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 10: New Posterior Medial Mucosal Margin

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 11: Final Posterior Medial Margin

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

[REDACTED]

Source: NCI Genomic Data Commons file 2a4e67df-294f-4ad1-9ee4-e6d50fff0f3a (TCGA-CN-6013.A6161EF5-FA7A-4465-8B3E-0A82A318CADA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).